Gene-level copy-number profile of tumor specimen TCGA-CC-A8HU-01A from TCGA case TCGA-CC-A8HU, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 39.3 years (14,367 days).
Specimen TCGA-CC-A8HU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.ad1ca343-f8ae-4f89-9e6e-9e0d77479d2a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CC-A8HU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/914d3a90-74d7-427a-9de9-c9f8b6947615

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11,292; copy number 2: 31,272; copy number 3: 13,899; copy number 4: 2,099; copy number 5: 833; copy number 6: 360; copy number 7: 8; copy number 9: 33; copy number 26: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CC-A8HU-01A-11D-A35Y-01): tumor purity 0.89, ploidy 2.17, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,251 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:44,712–32,882,874, 567 genes, copy number 5 (broad region; genes not listed).
- chr13:20,403,666–20,962,195, 17 genes, copy number 26 (within-gene range 17–26): CRYL1, MIR4499, AL590096.1, IFT88, SLC35E1P1, RNU2-7P, AL161772.1, IL17D, AL512652.2, EEF1AKMT1, RANP8, AL512652.1, XPO4, CNOT4P1, HNRNPA1P30, PPIAP27, RPSAP54.
- chr13:84,867,514–84,902,424, 1 gene, copy number 6: AL445588.1.
- chr13:85,363,601–114,337,626, 400 genes, copy number 6–9 (broad region; genes not listed).
- chr20:54,475,593–64,313,132, 266 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11,292. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
